Somatic mutation profile of tumor specimen 0DQQBY from CCDI case PBCFLD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 17.8 years (6,504 days).
Specimen 0DQQBY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52848a0b-d0ed-41e2-984d-f68d6c921aa9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQQCV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ce255c3-69b1-4757-9645-530366fe3ad5

The open-access MAF lists 40 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Intron 2, Nonsense Mutation 2, 3'UTR 2, In Frame Del 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 106/256 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, mutect2, varscan2
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 217/521 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 216/531 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGAP2 | c.1222C>T p.R408C (on ENST00000547588 / NM_001122772.2; = p.R72C on NM_014770.4) | Missense Mutation (SNP) | VAF 122/279 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs748818725, COSV57727366, COSV57729456; called by muse, mutect2, varscan2
- ATRX | c.4540C>T p.R1514* | Nonsense Mutation (SNP) | VAF 142/326 reads (44%) | catalogued as COSV64871896; called by muse, mutect2, varscan2
- CELSR3 | c.2395C>T p.R799W | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349601468; called by muse, mutect2, varscan2
- CFDP1 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 223/483 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.408); catalogued as rs1167003522; called by muse, mutect2, varscan2
- HIVEP3 | c.1423G>A p.V475M | Missense Mutation (SNP) | VAF 216/465 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs762501138, COSV56021649; called by muse, mutect2, varscan2
- PCLO | c.4876C>T p.R1626C | Missense Mutation (SNP) | VAF 314/734 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs766390746, COSV61650958; called by muse, mutect2, varscan2
- PDGFRA | c.869G>A p.C290Y | Missense Mutation (SNP) | VAF 341/653 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57276228; called by muse, mutect2, varscan2
- RIMS2 | c.3644C>T p.S1215L | Missense Mutation (SNP) | VAF 150/385 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs765899899, COSV99169759; called by muse, mutect2, varscan2
- CLEC1B | c.296G>A p.C99Y | Missense Mutation (SNP) | VAF 194/477 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FSIP2 | c.15242C>T p.S5081F | Missense Mutation (SNP) | VAF 209/425 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- H4C4 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 241/544 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- HMGN5 | c.737A>T p.E246V | Missense Mutation (SNP) | VAF 292/722 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- IZUMO3 | c.13T>C p.W5R | Missense Mutation (SNP) | VAF 83/332 reads (25%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MED12 | c.2974C>T p.L992F | Missense Mutation (SNP) | VAF 16/522 reads (3%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.536); called by muse, mutect2
- PCSK1 | c.1247A>T p.E416V | Missense Mutation (SNP) | VAF 23/516 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- POGLUT1 | c.890G>A p.W297* | Nonsense Mutation (SNP) | VAF 54/246 reads (22%) | called by muse, mutect2, varscan2
- SLC35F4 | c.1195C>T p.P399S (on ENST00000339762 / NM_001352015.2; = p.P363S on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/532 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- STK32B | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 166/369 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TLR4 | c.1679A>G p.K560R (on ENST00000355622 / NM_138554.5; = p.K520R on NM_003266.4) | Missense Mutation (SNP) | VAF 101/891 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TTN | c.69420_69422del p.E23140del (on ENST00000591111; = p.E15716del on NM_003319.4) | In Frame Del (DEL) | VAF 230/569 reads (40%) | called by pindel, varscan2
- WNK4 | c.3110C>T p.T1037I | Missense Mutation (SNP) | VAF 317/651 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DIP2C | c.3142C>T p.L1048= | Silent (SNP) | VAF 25/305 reads (8%) | catalogued as rs753915089; called by muse, mutect2
- EXTL1 | c.1812G>A p.V604= | Silent (SNP) | VAF 221/559 reads (40%) | called by muse, mutect2, varscan2
- H2AB1 | c.87G>A p.S29= | Silent (SNP) | VAF 68/1529 reads (4%) | catalogued as COSV57705337; called by muse, mutect2
- KIF13B | c.4281C>T p.P1427= | Silent (SNP) | VAF 36/340 reads (11%) | catalogued as rs367799854; called by muse, mutect2, varscan2
- MORC4 | c.2031T>C p.G677= | Silent (SNP) | VAF 250/617 reads (41%) | called by muse, mutect2, varscan2
- MT1HL1 | c.21C>T p.C7= | Silent (SNP) | VAF 341/714 reads (48%) | catalogued as rs750910445, COSV101516185; called by muse, mutect2, varscan2
- MYH8 | c.3990C>T p.N1330= | Silent (SNP) | VAF 337/745 reads (45%) | catalogued as rs199830005, COSV67963296; called by muse, mutect2, varscan2
- OTOG | c.7083C>A p.I2361= | Silent (SNP) | VAF 200/495 reads (40%) | called by muse, mutect2, varscan2
- PLXNA3 | c.4923C>T p.R1641= | Silent (SNP) | VAF 271/602 reads (45%) | catalogued as rs1268449346, COSV63753951; called by muse, mutect2, varscan2
- SOHLH1 | c.405G>A p.T135= | Silent (SNP) | VAF 261/575 reads (45%) | catalogued as rs760556303, COSV53683552; called by muse, mutect2, varscan2
- AMZ2 | chr17:68248022 C>A | 5'Flank (SNP) | VAF 62/134 reads (46%) | called by muse, mutect2, varscan2
- BARX1 | c.-64del | 5'UTR (DEL) | VAF 9/19 reads (47%) | called by mutect2, varscan2
- GRB7 | c.*31C>A | 3'UTR (SNP) | VAF 157/408 reads (38%) | catalogued as COSV100485387, COSV58449053; called by muse, mutect2, varscan2
- NF1 | c.4111-22T>C | Intron (SNP) | VAF 101/257 reads (39%) | called by muse, mutect2, varscan2
- TBC1D20 | c.*32T>C | 3'UTR (SNP) | VAF 95/181 reads (52%) | catalogued as rs200090125; called by muse, mutect2, varscan2
- TTN | c.10360+2928C>T | Intron (SNP) | VAF 50/712 reads (7%) | catalogued as rs144330952, COSV60194225; ClinVar: uncertain significance; called by muse, mutect2
